Somatic mutation profile of tumor specimen 0DGDW6 from CCDI case PBBTDD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 11.4 years (4,160 days).
Specimen 0DGDW6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 718b781e-425b-4c66-8de4-7e47ff7e7d89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGB93 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1830d6c4-1ece-44df-a743-a2bddfcfb9e0

The open-access MAF lists 89 somatic variants for this specimen: 56 protein-altering or splice-affecting, 15 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 15, Intron 10, 5'UTR 3, Nonsense Mutation 3, 3'UTR 2, 3'Flank 2, Frame Shift Ins 2, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 148/317 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG1 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 119/342 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.041); catalogued as COSV59200565; called by muse, mutect2, varscan2
- BACH2 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as COSV57591533; called by muse, mutect2, varscan2
- C12orf4 | c.624G>A p.W208* | Nonsense Mutation (SNP) | VAF 55/176 reads (31%) | catalogued as rs1333415372; called by muse, mutect2, varscan2
- CHRNE | c.1100C>G p.S367W | Missense Mutation (SNP) | VAF 108/261 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs753495337; called by muse, mutect2, varscan2
- DAB2 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57919429; called by muse, mutect2, varscan2
- DNMT3B | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs544561079, COSV52424914; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTNB | c.1705G>C p.G569R | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56482899; called by muse, mutect2
- FAM110A | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1171106146; called by muse, mutect2, varscan2
- FAM160A2 | c.2063G>C p.G688A (on ENST00000449352 / NM_001098794.2; = p.G702A on NM_032127.4) | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.521); catalogued as COSV56414805; called by muse, mutect2
- FGG | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 62/200 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs750711649, COSV60194984; called by muse, mutect2, varscan2
- HPS3 | c.2530G>A p.V844I | Missense Mutation (SNP) | VAF 50/410 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs758569835, COSV56054608; called by muse, mutect2
- KIF2C | c.1762C>A p.L588M | Missense Mutation (SNP) | VAF 114/360 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64765681; called by muse, mutect2, varscan2
- KRTAP10-1 | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs587597005, COSV100553367; called by muse, mutect2, varscan2
- LAMB3 | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.434); catalogued as CM1212274; called by muse, mutect2, varscan2
- MST1R | c.3236G>A p.R1079Q | Missense Mutation (SNP) | VAF 169/437 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs367999599; called by muse, mutect2, varscan2
- OR9A2 | c.269G>A p.R90K | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV63306799; called by muse, mutect2, varscan2
- OR9G1 | c.385C>G p.L129V | Missense Mutation (SNP) | VAF 88/987 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100380585; called by muse, mutect2
- PCMTD2 | c.100A>G p.R34G | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1188020782; called by muse, mutect2, varscan2
- POTEI | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as rs551179676; called by mutect2, varscan2
- SPRING1 | c.535-1G>A p.X179_splice | Splice Site (SNP) | VAF 63/358 reads (18%) | catalogued as COSV54339661; called by muse, mutect2, varscan2
- SRXN1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757818892; called by muse, mutect2, varscan2
- TMPRSS11F | c.440A>G p.E147G | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as COSV62467658; called by muse, varscan2
- TNKS1BP1 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1245668361; called by muse, mutect2, varscan2
- TRMT9B | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 96/507 reads (19%) | catalogued as rs372924745; called by muse, mutect2, varscan2
- ABCD2 | c.1795T>C p.W599R | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACSS2 | c.1296G>T p.L432F | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF11 | c.1055C>A p.A352E | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ATP13A4 | c.3226C>A p.L1076M | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- BCAN | c.957C>A p.S319R | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.95); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- BCOR | c.4184_4197dup p.R1400Gfs*89 (on ENST00000378444 / NM_001123385.2; = p.R1366Gfs*89 on NM_017745.6) | Frame Shift Ins (INS) | VAF 74/122 reads (61%) | called by mutect2, varscan2
- CYP4F3 | c.139C>A p.R47S | Missense Mutation (SNP) | VAF 118/371 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- EPB41L4A | c.1408C>A p.L470I | Missense Mutation (SNP) | VAF 30/367 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- FCGBP | c.6879G>T p.L2293F | Missense Mutation (SNP) | VAF 86/423 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- FCGR3B | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 118/142 reads (83%) | SIFT tolerated (0.21); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FUT5 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 62/330 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRIP2 | c.2052C>A p.D684E (on ENST00000619221; = p.D587E on NM_001080423.4) | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- HSPG2 | c.11408A>C p.D3803A | Missense Mutation (SNP) | VAF 80/240 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MMRN2 | c.1586A>G p.D529G | Missense Mutation (SNP) | VAF 135/180 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MUC16 | c.12115G>T p.G4039C | Missense Mutation (SNP) | VAF 68/299 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.85); called by muse, mutect2
- NAV3 | c.2870C>T p.A957V | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NCOA2 | c.408_410del p.V137del | In Frame Del (DEL) | VAF 44/436 reads (10%) | called by mutect2, pindel
- NOL8 | c.3120G>T p.Q1040H | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- NOTUM | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- OBSCN | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 81/230 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- OR13A1 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- PREX2 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 139/813 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRR36 | c.1957dup p.S653Ffs*353 | Frame Shift Ins (INS) | VAF 27/118 reads (23%) | called by mutect2, pindel, varscan2
- ROS1 | c.4505A>T p.D1502V | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, varscan2
- SHISA9 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC23A3 | c.772C>T p.P258S (on ENST00000409878 / NM_001144889.2; = p.L247= on NM_144712.5) | Missense Mutation (SNP) | VAF 98/340 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SPDYE6 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 38/382 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- TMEM161A | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 78/270 reads (29%) | called by muse, mutect2, varscan2
- TRMO | c.1088A>T p.K363I | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- VPS13B | c.4186C>A p.Q1396K | Missense Mutation (SNP) | VAF 90/577 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF518B | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ARR3 | c.360G>T p.L120= | Silent (SNP) | VAF 80/96 reads (83%) | catalogued as rs1029995310, COSV57203209; called by muse, mutect2, varscan2
- CAB39L | c.694C>T p.L232= | Silent (SNP) | VAF 47/182 reads (26%) | called by muse, mutect2, varscan2
- EMILIN1 | c.1572G>A p.A524= | Silent (SNP) | VAF 63/287 reads (22%) | catalogued as rs759528710, COSV53153225; called by muse, mutect2, varscan2
- GRM5 | c.456T>C p.S152= | Silent (SNP) | VAF 22/556 reads (4%) | called by muse, mutect2
- JHY | c.894G>A p.K298= | Silent (SNP) | VAF 74/389 reads (19%) | called by muse, mutect2, varscan2
- LRRC8E | c.1296C>G p.T432= | Silent (SNP) | VAF 51/210 reads (24%) | catalogued as rs774461112; called by muse, mutect2, varscan2
- LRRN4 | c.1890C>T p.Y630= | Silent (SNP) | VAF 38/220 reads (17%) | catalogued as rs1180019307, COSV66646675; called by muse, mutect2, varscan2
- OSBP | c.952C>T p.L318= | Silent (SNP) | VAF 77/478 reads (16%) | called by muse, mutect2, varscan2
- RPS8 | c.339C>T p.Y113= | Silent (SNP) | VAF 93/267 reads (35%) | called by muse, mutect2, varscan2
- SALL3 | c.1236C>T p.S412= | Silent (SNP) | VAF 55/133 reads (41%) | catalogued as rs201160407, COSV101609953; called by muse, mutect2, varscan2
- STOML3 | c.126C>G p.T42= | Silent (SNP) | VAF 53/248 reads (21%) | called by muse, mutect2, varscan2
- TK1 | c.498C>T p.L166= | Silent (SNP) | VAF 68/193 reads (35%) | catalogued as rs781163864; called by muse, mutect2, varscan2
- TNS1 | c.1539G>A p.A513= | Silent (SNP) | VAF 83/287 reads (29%) | catalogued as rs758873247; called by muse, mutect2, varscan2
- VAC14 | c.2142G>A p.S714= | Silent (SNP) | VAF 188/483 reads (39%) | catalogued as rs1195310053, COSV99935287; called by muse, varscan2
- VPS13B | c.10725C>T p.H3575= | Silent (SNP) | VAF 102/617 reads (17%) | catalogued as rs372367817; ClinVar: likely benign; called by muse, mutect2, varscan2
- AC053503.6 | c.892-47C>G | Intron (SNP) | VAF 34/281 reads (12%) | catalogued as rs559033573; called by muse, mutect2, varscan2
- C16orf97 | n.374C>T | RNA (SNP) | VAF 61/191 reads (32%) | called by muse, mutect2, varscan2
- CES2 | c.-16_-3del | 5'UTR (DEL) | VAF 59/254 reads (23%) | called by mutect2, pindel, varscan2
- COL20A1 | c.2807-38G>T | Intron (SNP) | VAF 82/285 reads (29%) | called by muse, mutect2, varscan2
- ERVFRD-1 | c.-35C>A | 5'UTR (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- GPHB5 | chr14:63312911 G>T | 3'Flank (SNP) | VAF 66/209 reads (32%) | called by muse, mutect2, varscan2
- ITGA5 | c.2842-13C>A | Intron (SNP) | VAF 28/87 reads (32%) | called by muse, mutect2, varscan2
- KLK1 | c.497-32G>T | Intron (SNP) | VAF 45/131 reads (34%) | called by muse, mutect2, varscan2
- MYOT | c.1324+57A>C | Intron (SNP) | VAF 33/96 reads (34%) | called by muse, mutect2, varscan2
- NR1H3 | c.44-87T>C | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2
- NXF1 | c.*3G>A | 3'UTR (SNP) | VAF 59/359 reads (16%) | catalogued as rs1441176564, COSV53674957; called by muse, mutect2, varscan2
- PC | c.1514-34G>T | Intron (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- PWWP2B | c.*115dup | 3'UTR (INS) | VAF 147/250 reads (59%) | called by mutect2, pindel, varscan2
- SLC22A5 | c.394-272G>T | Intron (SNP) | VAF 13/34 reads (38%) | called by mutect2, varscan2
- SLC4A8 | c.2010+106C>T | Intron (SNP) | VAF 26/58 reads (45%) | catalogued as rs112197384, COSV100177332; called by muse, mutect2, varscan2
- TBC1D26 | c.666+51C>A | Intron (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- TSHZ1 | c.-52G>T | 5'UTR (SNP) | VAF 22/45 reads (49%) | called by muse, varscan2
- TUBGCP4 | chr15:43409761 C>T | 3'Flank (SNP) | VAF 32/96 reads (33%) | catalogued as rs767900840; called by muse, mutect2, varscan2
